CPTAC case C3N-01905 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dfea15bc-20f4-4c35-bf8b-b212960dfa62

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 59.2 years (21,631 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R1; Days to last known disease status: 1,854 days (5.1 years); Progression or recurrence: yes; Days to recurrence: 1,449 days (4.0 years); Days to last follow up: 1,854 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm (a second GDC size field records 2.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Involved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 408 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 756 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,106 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,512 days (4.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,449 days (4.0 years).
- Days to follow up: 1,512 days (4.1 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 1,854.

Other clinical attributes
- Weight: 95 kg; Height: 175 cm; BMI: 31.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 39; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 44; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01905-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 290 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01905-21: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-01905-09: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 527 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01905-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -16 days; Method of sample procurement: Blood Draw.
